Surgical pathology report (de-identified scan), TCGA case TCGA-B9-7268, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-7268-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Diagnosis:

Kidney, left, partial nephrectomy

Histologic tumor type/subtype: papillary renal cell carcinoma,
type 2

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 2 (of 4)

Tumor size (greatest dimension): 8.5 cm

Tumor focality: focal

Extent of tumor invasion (if present specify if macroscopic or
microscopic):

Capsular invasion/perirenal adipose tissue: absent

Gerota' s fascia: absent

Renal sinus: not applicable

Major veins (renal vein or segmental branches, IVC): not
applicable

Ureter: not applicable

Venous (large vessel): absent

Lymphatic (small vessel): absent

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): negative

Renal capsular margin (partial nephrectomy only): negative

Paranephric adipose tissue margin (partial nephrectomy only):
negative

Gerota' s fascia (nephrectomy): not applicable

Renal vein (nephrectomy): not applicable

Ureter (nephrectomy): not applicable

Adrenal gland: not submitted

Lymph nodes: none identified

AJCC Staging: pT2 pNx

[page 2 of 2]
This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

inical History:

█-year-old male with a left renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left kidney" and is a 159.8 gram 8.5 x 7.3 x 5.5 cm circumscribed soft nodule, partially covered with a predominantly intact capsule with a 1.3 cm irregular area of disruption. The exposed parenchymal margin is 5.7 x 5.2 cm and is inked black. The intact capsule is inked blue. Sectioning demonstrates a solid soft golden yellow/tan cut surface abutting blue and black inked capsular and parenchymal margins, respectively. It also communicates with the orange inked previously described defect. No cystic component is identified. There is a rim of renal parenchyma along the black inked surgical margin. There is a small amount of attached perinephric fat. The renal tissue at the periphery grossly appears unremarkable.

Block Summary:

Inking: capsule/blue, parenchyma/black, defect/yellow

A1 - tumor in relationship to black inked parenchymal margin

A2-A3 - tumor and overlying capsule

A4 - edge of defect

A5-A6 - central tumor

Source: NCI Genomic Data Commons file 23040455-2f03-4d3a-91d9-29b2cc7384a1 (TCGA-B9-7268.288FA268-6372-4F60-9D91-79DE9255E20B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).